CCDI case PBCHUD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/6825e0e5-07e7-4312-a904-3dadf58db30a

Demographics
Sex at birth: male.

Diagnoses (1)
1. Retinoblastoma, NOS: ICD-O-3 morphology code: 9510/3; Tissue or organ of origin: Retina; Age at diagnosis: 1.3 years (468 days).

Biospecimens (3 samples)
- Sample 0DTVG5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTVG7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DTVGA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
